Gene-level copy-number profile of tumor specimen TCGA-VS-A9UB-01A from TCGA case TCGA-VS-A9UB, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 54.0 years (19,737 days).
Specimen TCGA-VS-A9UB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.5ed71bad-4cba-4dc4-b9c7-6069c928b263.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A9UB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c35340ab-4660-4952-807c-d8f26533aa11

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 1,050; copy number 2: 39,779; copy number 3: 11,424; copy number 4: 7,537; copy number 6: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A9UB-01A-22D-A42N-01): tumor purity 0.55, ploidy 2.46, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:241,590,102–241,677,376, 3 genes (within-gene range 0–2): OPN3, CHML, AL133390.1.
- chr1:242,147,230–242,210,827, 3 genes: AL591686.2, RN7SKP12, AL591686.1.
- chr2:186,261,419–186,695,287, 7 genes (within-gene range 0–2): RPL23AP35, AC017071.1, MED28P3, ZC3H15, DPRXP1, ITGAV, AC017101.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:34,849,137–35,093,210, 11 genes, copy number 6: TUBAP11, AQR, AC018868.1, ZNF770, AC114546.3, AC114546.1, AC114546.4, AC114546.2, AC021231.3, NANOGP8, AC021231.2.
- chr15:35,121,573–35,122,084, 1 gene, copy number 6: PRELID1P4.

Autosomal genes at a single copy (total copy number 1): 1,048. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
